Somatic mutation profile of tumor specimen 0DDZ6V from CCDI case PBBNWB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.4 years (2,709 days).
Specimen 0DDZ6V: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f7cd350e-44a5-4791-8579-0bf7d03dcebc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDZ5Y (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/feebbbd8-4780-46d6-99bb-970106af6a06

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 8, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT3 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 278/768 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397514606, COSV55605820, COSV55624598; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 342/778 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- COL19A1 | c.1804C>T p.R602C | Missense Mutation (SNP) | VAF 420/483 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769148194; called by muse, mutect2, varscan2
- CSNK2A1 | c.136G>T p.G46C | Missense Mutation (SNP) | VAF 449/902 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53933729; called by muse, mutect2, varscan2
- FCRL3 | c.1887G>T p.R629S | Missense Mutation (SNP) | VAF 276/652 reads (42%) | SIFT tolerated (0.86); PolyPhen benign (0.007); catalogued as rs753341395; called by muse, mutect2, varscan2
- LILRB2 | c.1579G>A p.A527T | Missense Mutation (SNP) | VAF 286/629 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs527701689; called by muse, mutect2, varscan2
- PEG3 | c.1708G>A p.E570K | Missense Mutation (SNP) | VAF 186/412 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV55624758, COSV55640636; called by muse, mutect2, varscan2
- FAT4 | c.4954G>A p.E1652K | Missense Mutation (SNP) | VAF 64/981 reads (7%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.984); called by muse, mutect2
- KCNH6 | c.1194G>A p.A398= | Silent (SNP) | VAF 199/386 reads (52%) | catalogued as rs1421176285, COSV59004418; called by muse, mutect2, varscan2
- MAGEA3 | c.528C>T p.Y176= | Silent (SNP) | VAF 337/687 reads (49%) | called by muse, mutect2, varscan2
- TMEM39B | c.843C>T p.D281= | Silent (SNP) | VAF 176/440 reads (40%) | catalogued as rs750749250; called by muse, mutect2, varscan2
